Surgical pathology report (de-identified scan), TCGA case TCGA-06-A5U1, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Henry Ford Hospital, specimen TCGA-06-A5U1-01A (Primary Tumor).

[page 1 of 2]
CLF ICD-O-3
path Glioblastoma Multiforme 9440/3
Glioblastoma NOS 9440/3
Site ④ Brain, occipital
lobe C 71.4
JW 4/18/13

Surgical Pathology Report

Patient Name: Phone #: Accession #:
Med. Rec. #: Client: Taken:
DOB: Location: Received:
Gender: F Acnt: Reported:
Physician(s):

Clinical History

The patient is a -year-old woman who experienced confusion and difficulty finding words
On

imaging, there is a left temporal, ring-enhancing tumor associated with edema and mass effect. The
patient has a
past history of a lung lesion

Operative Diagnoses

Brain tumor

Operation / Specimen

A: Brain, left temporal tumor, excision biopsy

B: Brain, left temporal tumor, excision biopsy

Pathologic Diagnosis

A. and B. Brain, left temporal, biopsy and excision: Glioblastoma, WHO Grade IV (see comment).

Comment

Sections show a high-grade glioma demonstrating gemistocytic differentiation, high mitotic activity,
microvascular
proliferation and sheet (geographic) necrosis. The patient's tumor bank slides were also
reviewed.

IMMUNOHISTOCHEMISTRY: There is diffuse moderate-to-strong reactivity for p53. The mitotic index by
MIB-1 is up

to approximately 45%. Positive and negative controls show appropriate immunoreactivity.

Results of any additional ancillary studies will be reported in procedure addenda below.

Electronically Signed Out

Senior Staff Pathologist

Resident Pathologist

Procedures/Addenda

PCR for EGFR variant III mutation

Date Ordered: Date Reported:

Interpretation

NEGATIVE - No evidence of EGFRvIII mutation is detected

Surgical Pathology

Page 2 of 3

Results-Comments

TEST DESCRIPTION: Testing performed on RNA extracted from paraffin tissue block

H and E slide was examined and tumor DNA was enriched by microdissection

The epidermal growth factor receptor (EGFR) is an attractive molecular target in glioblastoma because it
is amplified,

overexpressed, and/or mutated in up to 40% to 50% of patients. Epidermal growth factor receptor variant
III

(EGFRvIII) is an oncogenic, constitutively active mutant form of EGFR that is commonly expressed in
glioblastoma.

[page 2 of 2]
Cell culture and in vivo models of glioblastoma have demonstrated EGFRvIII as defining prognostically distinct subgroups of glioblastomas. Additionally, the presence of EGFRvIII has been shown to sensitize tumors to EGFR tyrosine kinase inhibitors when the tumor suppressor protein PTEN is intact. RNA is extracted from formalin fixed, paraffin embedded tissue samples and reverse transcribed to cDNA. The cDNA is then amplified using standard PCR technique for DNA templates. PCR products are detected by gel electrophoresis. The limit of detection of this assay has been determined to be approximately 5 mutant cells in 100 normal cells.

FDA Comment: The above data are not to be construed as the results from a stand alone diagnostic test. This test was developed and its performance characteristics determined by the as required by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are provided for informational purposes only, and should be interpreted only in the context of established procedures and/or diagnostic criteria.

Electronically Signed Out

Staff Pathologist

MGMT Promoter Methylation

Date Ordered: Date Reported:

Interpretation

POSITIVE: Methylated MGMT promoter is detected.

Results-Comments

Testing performed on DNA extracted from tumor Neurosurgery sample

H and E slide was examined and no microdissection was needed.

TEST DESCRIPTION: Patients with glioma containing a methylated MGMT promoter have been shown to benefit

from therapy with alkylating agents. Assessment of MGMT promoter methylation status involves bisulfite treatment of

DNA followed by real-time PCR amplification of methylated and unmethylated DNA sequences. The

analytic sensitivity of this assay was determined by serial dilution of methylated positive control DNA into unmethylated DNA, and was assessed to be 1% of methylated DNA in the background of unmethylated DNA. Factors

such as the presence of >50% non-neoplastic cells in the sample, or extensive tissue necrosis, may preclude the

detection of methylated MGMT promoter sequences.

FDA COMMENT: The above data are not to be construed as the results from a stand alone diagnostic test. This test

was developed and its performance characteristics determined by the as required

by CLIA '88 regulations. It has not been cleared or approved for specific uses by the U.S. Food and Drug Administration (FDA). The FDA has determined that such clearance or approval is not necessary. These results are

provided for informational purposes only, and should be interpreted only in the context of established procedures

and/or diagnostic criteria.

Surgical Pathology

Source: NCI Genomic Data Commons file ddb520bc-15c6-4b74-91c8-3c793cd8e075 (TCGA-06-A5U1.5F19F1F8-73BF-4E7D-9169-2F2C25F33F2B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).